Gene-level copy-number profile of tumor specimen C3N-01419-03 from CPTAC case C3N-01419, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 58.7 years (21,422 days).
Specimen C3N-01419-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 396d1056-6158-42b3-98ba-e5b785980895.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01419-75 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/404c664a-aa54-42d3-b66e-ae9ea713f047

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 512; copy number 1: 4,057; copy number 2: 54,191; copy number 3: 147; copy number 4: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,716. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
